Gene-level copy-number profile of tumor specimen TCGA-58-A46M-01A from TCGA case TCGA-58-A46M, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.9 years (22,592 days).
Specimen TCGA-58-A46M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.26e8bfa7-8cd5-4a11-8b09-360d4300777e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-A46M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/76150bde-2e0b-4a40-9c75-b130d7220f4d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 1,679; copy number 2: 17,282; copy number 3: 17,225; copy number 4: 14,625; copy number 5: 5,259; copy number 6: 1,449; copy number 7: 825; copy number 8: 231; copy number 9: 490; copy number 10: 232; copy number 11: 58; copy number 12: 52; copy number 13: 370.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-A46M-01A-11D-A24C-01): tumor purity 0.55, ploidy 3.41, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,272,309–11,557,665, 1 gene (within-gene range 0–4): ATG7.
- chr3:11,488,300–11,529,755, 2 genes: AC026185.1, AC022001.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–5): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr13:54,572,354–54,819,238, 2 genes (within-gene range 0–2): AL442636.1, AL512655.1.
- chr13:63,034,668–65,310,953, 16 genes: AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1, LGMNP1, STARP1.
- chr16:7,431,217–7,431,296, 1 gene: AC007222.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,245 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:134,485,721–198,222,513, 1,096 genes, copy number 9–13 (broad region; genes not listed).
- chr5:165,349,030–166,382,599, 7 genes, copy number 7 (within-gene range 4–7): AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr5:178,237,618–181,342,213, 126 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:9,082,557–19,146,253, 105 genes, copy number 8 (broad region; genes not listed).
- chr8:36,378,069–39,417,378, 77 genes, copy number 7–10 (within-gene range 1–10) (broad region; genes not listed).
- chr9:90,158,028–90,752,230, 8 genes, copy number 7: AL353649.1, OR7E31P, OR7E116P, LINC01508, LINC01501, DIRAS2, OR7E109P, OR7E108P.
- chr9:98,288,109–102,657,514, 68 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr13:57,631,744–57,729,311, 1 gene, copy number 7 (within-gene range 2–7): PCDH17.
- chr13:57,991,350–57,991,464, 1 gene, copy number 7: RNA5SP30.
- chr13:62,321,305–62,796,714, 7 genes, copy number 9 (within-gene range 0–9): LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448.
- chr18:27,335,968–29,650,440, 19 genes, copy number 9–12: AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr20:87,250–35,292,425, 730 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
